Somatic mutation profile of tumor specimen 6a9a1d66-d666-44df-a68e-ddc58d (aliquot 6a9a1d66-d666-44df-a68e-ddc58d_D6_1) from CPTAC case 16CO012, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage I.
Specimen 6a9a1d66-d666-44df-a68e-ddc58d: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8ff03bdb-2e61-4782-95df-8804eb491f2e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen dd8edec7-4c65-4a5a-b670-777661 (Blood Derived Normal), aliquot dd8edec7-4c65-4a5a-b670-777661_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/29c2b0c1-1280-42e1-bb05-ce3080032667

The open-access MAF lists 146 somatic variants for this specimen: 90 protein-altering or splice-affecting, 31 silent, 25 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 31, Intron 19, Nonsense Mutation 8, RNA 4, Frame Shift Del 3, Frame Shift Ins 2, In Frame Ins 1, 3'UTR 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 155/435 reads (36%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen benign (0.44); catalogued as rs112445441, CM125166, COSV55497357, COSV55497388, COSV55522580; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 9/44 reads (20%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- AC244197.3 | c.257G>A p.R86H | Missense Mutation (SNP) | VAF 145/546 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); catalogued as rs1290154616; called by muse, mutect2, varscan2
- ACVR1C | c.1429C>T p.R477C | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1376322387, COSV54643947; called by muse, mutect2, varscan2
- BCO1 | c.683G>A p.R228H | Missense Mutation (SNP) | VAF 157/593 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.025); catalogued as rs747676129, COSV50729947; called by muse, mutect2, varscan2
- BRSK2 | c.1219G>A p.G407S | Missense Mutation (SNP) | VAF 44/173 reads (25%) | SIFT tolerated (0.47); PolyPhen benign (0.02); catalogued as rs368608811; called by muse, mutect2, varscan2
- CAMTA1 | c.1879G>A p.V627I | Missense Mutation (SNP) | VAF 142/340 reads (42%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); catalogued as rs775433901, COSV100352348; ClinVar: likely benign; called by muse, mutect2, varscan2
- CHRNA4 | c.1426G>A p.E476K | Missense Mutation (SNP) | VAF 36/77 reads (47%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0.001); catalogued as rs201420419, COSV64719306; called by muse, mutect2, varscan2
- CNTN5 | c.869G>A p.R290H | Missense Mutation (SNP) | VAF 30/127 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.67); catalogued as rs773856381, COSV54315938; called by muse, mutect2, varscan2
- CUX2 | c.1925C>T p.T642M | Missense Mutation (SNP) | VAF 48/231 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779165497, COSV55628422; called by muse, mutect2, varscan2
- EDNRA | c.1255C>T p.R419W | Missense Mutation (SNP) | VAF 41/155 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.53); catalogued as rs761439706; called by muse, mutect2, varscan2
- ELAVL2 | c.502G>A p.V168I | Missense Mutation (SNP) | VAF 35/278 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs139149645; called by muse, mutect2, varscan2
- EPHA6 | c.124C>T p.R42C | Missense Mutation (SNP) | VAF 9/127 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); catalogued as rs1164218979, COSV101061596; called by muse, mutect2
- EXOC4 | c.1573C>T p.R525* | Nonsense Mutation (SNP) | VAF 114/320 reads (36%) | catalogued as rs1446395002, COSV54090129; called by muse, varscan2
- FAM160B2 | c.1727G>A p.R576H | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.54); PolyPhen possibly damaging (0.891); catalogued as rs752025525, COSV57157148; called by muse, mutect2, varscan2
- GPER1 | c.682G>A p.A228T | Missense Mutation (SNP) | VAF 63/258 reads (24%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.558); catalogued as rs771448862, COSV99867392; called by muse, mutect2, varscan2
- GPR139 | c.527G>A p.S176N | Missense Mutation (SNP) | VAF 102/363 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.396); catalogued as COSV100430060; called by muse, mutect2, varscan2
- GRIA1 | c.2000G>A p.G667E | Missense Mutation (SNP) | VAF 19/407 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53598315; called by muse, mutect2
- GRM7 | c.778C>T p.R260C | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.683); catalogued as rs754807278, COSV63135646; called by muse, mutect2, varscan2
- IFNA21 | c.493G>A p.E165K | Missense Mutation (SNP) | VAF 51/213 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs200041157; called by muse, mutect2, varscan2
- IFNA4 | c.321A>T p.K107N | Missense Mutation (SNP) | VAF 37/293 reads (13%) | SIFT tolerated (0.09); PolyPhen benign (0.371); catalogued as COSV101427066; called by muse, mutect2, varscan2
- KCNK2 | c.1097C>T p.S366L (on ENST00000444842 / NM_001017425.3; = p.S351L on NM_014217.4) | Missense Mutation (SNP) | VAF 70/498 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs769208249, COSV67204202; called by muse, mutect2, varscan2
- KIAA1522 | c.1501C>T p.P501S (on ENST00000373480 / NM_001198972.2; = p.P560S on NM_020888.3) | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as rs774798130; called by muse, mutect2
- KIF21B | c.1049C>A p.S350* | Nonsense Mutation (SNP) | VAF 38/563 reads (7%) | catalogued as COSV100143687; called by muse, mutect2
- LENG9 | c.394G>A p.G132S | Missense Mutation (SNP) | VAF 44/166 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs781081009; called by muse, mutect2, varscan2
- MAGEB6 | c.304G>A p.V102I | Missense Mutation (SNP) | VAF 144/494 reads (29%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as rs201693952, COSV66872886; called by mutect2, varscan2
- MAPK8IP3 | c.1589G>A p.R530H | Missense Mutation (SNP) | VAF 40/145 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373615838; called by muse, mutect2, varscan2
- MSC | c.560G>C p.R187T | Missense Mutation (SNP) | VAF 46/299 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); catalogued as COSV100335622; called by muse, mutect2, varscan2
- MYO15A | c.3275C>T p.A1092V | Missense Mutation (SNP) | VAF 73/268 reads (27%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as rs1271240611, COSV99233887; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MYT1 | c.2036G>A p.R679Q | Missense Mutation (SNP) | VAF 16/196 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.283); catalogued as rs762700208, COSV100115409, COSV60509931; called by muse, mutect2
- NTN5 | c.328G>A p.A110T | Missense Mutation (SNP) | VAF 38/170 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.007); catalogued as rs776896369, COSV54308983; called by muse, mutect2, varscan2
- OR10H5 | c.772G>A p.V258I | Missense Mutation (SNP) | VAF 50/186 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.01); catalogued as rs372973246, COSV100454604; called by muse, mutect2
- OR6K3 | c.827G>A p.R276H (on ENST00000368146; = p.R260H on NM_001005327.2) | Missense Mutation (SNP) | VAF 30/388 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.344); catalogued as rs145239299; called by muse, mutect2
- PCDHGA11 | c.1672G>A p.D558N | Missense Mutation (SNP) | VAF 82/396 reads (21%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (1); catalogued as COSV53955468; called by muse, mutect2, varscan2
- PCDHGA6 | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 30/350 reads (9%) | SIFT tolerated, low confidence (0.55); PolyPhen benign (0.106); catalogued as rs769907625, COSV53937174, COSV54024971; called by muse, mutect2
- PIP5K1C | c.1979del p.P660Rfs*225 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | catalogued as rs748532409; called by pindel, varscan2
- PPP1R21 | c.1643G>A p.R548H | Missense Mutation (SNP) | VAF 30/102 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs764506978; called by muse, mutect2, varscan2
- PYROXD2 | c.16C>T p.R6* | Nonsense Mutation (SNP) | VAF 12/168 reads (7%) | catalogued as rs764535970; called by muse, mutect2
- RIPK4 | c.613G>T p.D205Y | Missense Mutation (SNP) | VAF 28/115 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs768158256, COSV60185763; called by muse, mutect2, varscan2
- RNF113B | c.910G>A p.A304T | Missense Mutation (SNP) | VAF 30/150 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs774767836, COSV57434757; called by muse, mutect2, varscan2
- RNF43 | c.1039G>A p.G347S | Missense Mutation (SNP) | VAF 17/82 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.978); catalogued as rs780224400, COSV68459804; called by muse, mutect2, varscan2
- RTL1 | c.2005C>T p.R669C | Missense Mutation (SNP) | VAF 79/326 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as rs1566753444; called by muse, mutect2, varscan2
- RYR1 | c.5234C>T p.T1745M | Missense Mutation (SNP) | VAF 175/811 reads (22%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.991); catalogued as rs377476955; called by muse, mutect2, varscan2
- SCGB1D4 | c.199G>A p.D67N | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.638); catalogued as rs149931773, COSV62203927, COSV62203971; called by muse, mutect2, varscan2
- SCN2A | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 68/258 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs1482814284, COSV51860027; called by muse, varscan2
- SETBP1 | c.1687C>T p.P563S | Missense Mutation (SNP) | VAF 87/406 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56319457; called by muse, mutect2, varscan2
- SHCBP1L | c.223G>A p.A75T | Missense Mutation (SNP) | VAF 5/72 reads (7%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.026); catalogued as COSV62354877; called by muse, mutect2
- SLC25A6 | c.268G>A p.A90T | Missense Mutation (SNP) | VAF 201/827 reads (24%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as rs747847057; called by muse, mutect2, varscan2
- SLC9A3R2 | c.914C>T p.T305M (on ENST00000424542 / NM_001130012.3; = p.T294M on NM_004785.6) | Missense Mutation (SNP) | VAF 39/346 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377126399; called by muse, mutect2, varscan2
- SPRY3 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 41/1289 reads (3%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs775484840, COSV57143637; called by muse, mutect2
- STK32B | c.503C>T p.A168V | Missense Mutation (SNP) | VAF 22/179 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as rs778314748; called by muse, mutect2, varscan2
- SYT6 | c.952G>A p.D318N (on ENST00000610222 / NM_001366225.1; = p.D233N on NM_205848.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 102/309 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs779569231; called by muse, mutect2, varscan2
- TPCN2 | c.563G>A p.R188Q | Missense Mutation (SNP) | VAF 43/239 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs536512909, COSV53728314; called by muse, mutect2, varscan2
- TTPA | c.184G>T p.D62Y | Missense Mutation (SNP) | VAF 28/89 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1315324866; called by muse, mutect2, varscan2
- WDR4 | c.1178C>T p.P393L | Missense Mutation (SNP) | VAF 54/204 reads (26%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs765182735, COSV57735954; called by muse, mutect2, varscan2
- WDR87 | c.2378G>A p.R793H | Missense Mutation (SNP) | VAF 57/204 reads (28%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.914); catalogued as rs566790427; called by muse, mutect2, varscan2
- XRRA1 | c.1552C>T p.R518W | Missense Mutation (SNP) | VAF 124/519 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs371407553, COSV58498040; called by muse, mutect2, varscan2
- ZFHX4 | c.10224C>A p.C3408* | Nonsense Mutation (SNP) | VAF 19/378 reads (5%) | catalogued as COSV50478726, COSV50507342; called by muse, mutect2
- ZNF547 | c.302G>A p.R101H | Missense Mutation (SNP) | VAF 50/219 reads (23%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs753794377; called by muse, mutect2, varscan2
- ACVR1B | c.137G>A p.C46Y | Missense Mutation (SNP) | VAF 113/318 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ALDH1L2 | c.1107del p.F369Lfs*45 | Frame Shift Del (DEL) | VAF 44/166 reads (27%) | called by mutect2, pindel, varscan2
- APC | c.4247_4248delinsT p.G1416Vfs*3 | Frame Shift Del (DEL) | VAF 63/309 reads (20%) | called by pindel, varscan2*
- APOA4 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 44/447 reads (10%) | SIFT tolerated (0.15); PolyPhen benign (0.049); called by muse, mutect2
- ARMH2 | c.319T>G p.L107V | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.787); called by muse, mutect2, varscan2
- BAHD1 | c.2327T>G p.L776R | Missense Mutation (SNP) | VAF 36/174 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, varscan2
- CATSPERE | c.1213G>C p.V405L | Missense Mutation (SNP) | VAF 114/223 reads (51%) | SIFT tolerated (1); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- CELSR2 | c.6610C>G p.L2204V | Missense Mutation (SNP) | VAF 107/245 reads (44%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.872); called by muse, mutect2, varscan2
- CFDP1 | c.221A>T p.E74V | Missense Mutation (SNP) | VAF 45/178 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.08); called by muse, mutect2, varscan2
- CTNS | c.286C>T p.Q96* | Nonsense Mutation (SNP) | VAF 36/666 reads (5%) | called by muse, mutect2
- DUOX1 | c.3407C>T p.T1136I | Missense Mutation (SNP) | VAF 89/349 reads (26%) | SIFT tolerated (0.27); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FOXD4L4 | c.1141G>A p.G381R | Missense Mutation (SNP) | VAF 33/800 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); called by muse, mutect2
- GALNT17 | c.1552A>G p.T518A | Missense Mutation (SNP) | VAF 108/367 reads (29%) | SIFT tolerated (0.47); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GDF7 | c.1132T>C p.C378R | Missense Mutation (SNP) | VAF 78/444 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GSPT2 | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 27/278 reads (10%) | called by muse, mutect2
- HAS1 | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 10/160 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.015); called by muse, mutect2
- HCN4 | c.808C>G p.L270V | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KCNQ3 | c.1224T>G p.F408L | Missense Mutation (SNP) | VAF 82/429 reads (19%) | SIFT tolerated (0.43); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LOXL3 | c.1546A>G p.T516A | Missense Mutation (SNP) | VAF 63/210 reads (30%) | SIFT tolerated (0.41); PolyPhen benign (0); called by muse, mutect2, varscan2
- LZTS1 | c.1032G>T p.Q344H | Missense Mutation (SNP) | VAF 55/215 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.804); called by muse, mutect2, varscan2
- MED23 | c.2957C>G p.T986S | Missense Mutation (SNP) | VAF 54/252 reads (21%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.496); called by muse, mutect2, varscan2
- OR4A47 | c.551_558dup p.C187Nfs*13 | Frame Shift Ins (INS) | VAF 55/295 reads (19%) | called by mutect2, varscan2
- PLXNA2 | c.2441G>A p.C814Y | Missense Mutation (SNP) | VAF 14/328 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2
- SMUG1 | c.121G>T p.E41* | Nonsense Mutation (SNP) | VAF 69/420 reads (16%) | called by muse, mutect2, varscan2
- SNX18 | c.800C>T p.P267L | Missense Mutation (SNP) | VAF 14/234 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.655); called by muse, mutect2
- SOX9 | c.1163dup p.P389Afs*189 | Frame Shift Ins (INS) | VAF 10/57 reads (18%) | called by mutect2, pindel, varscan2
- SPTAN1 | c.3034C>T p.R1012C | Missense Mutation (SNP) | VAF 132/624 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- SPTBN5 | c.9042G>A p.W3014* | Nonsense Mutation (SNP) | VAF 11/119 reads (9%) | called by muse, mutect2
- STK39 | c.1147_1152dup p.E383_W384dup | In Frame Ins (INS) | VAF 34/183 reads (19%) | called by mutect2, varscan2
- TAF5L | c.706G>A p.E236K | Missense Mutation (SNP) | VAF 36/370 reads (10%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.881); called by muse, mutect2
- ZNF716 | c.1162G>T p.A388S | Missense Mutation (SNP) | VAF 16/250 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.01); called by muse, mutect2
- APH1A | c.789C>T p.P263= | Silent (SNP) | VAF 63/199 reads (32%) | catalogued as rs376130182; called by muse, mutect2, varscan2
- APOB | c.555C>T p.N185= | Silent (SNP) | VAF 59/754 reads (8%) | catalogued as COSV51954099; called by muse, mutect2
- ASTN2 | c.684C>T p.Y228= | Silent (SNP) | VAF 18/94 reads (19%) | catalogued as rs753397797, COSV57754418; called by muse, mutect2, varscan2
- CCN4 | c.324G>A p.P108= | Silent (SNP) | VAF 66/507 reads (13%) | catalogued as rs750979606, COSV51531755; called by muse, mutect2, varscan2
- CEP192 | c.6909C>T p.D2303= | Silent (SNP) | VAF 14/123 reads (11%) | catalogued as rs766728012, COSV58059813; called by muse, mutect2
- FAM135B | c.21G>A p.T7= | Silent (SNP) | VAF 14/141 reads (10%) | catalogued as rs200745364, COSV50531107; called by muse, mutect2, varscan2
- FREM3 | c.900C>T p.A300= | Silent (SNP) | VAF 52/176 reads (30%) | catalogued as rs1202286337; called by muse, mutect2, varscan2
- GAD2 | c.153C>T p.D51= | Silent (SNP) | VAF 9/37 reads (24%) | catalogued as rs770305917, COSV52166762; called by muse, mutect2, varscan2
- GFPT1 | c.2001C>T p.S667= (on ENST00000357308 / NM_001244710.2; = p.S649= on NM_002056.4) | Silent (SNP) | VAF 65/341 reads (19%) | catalogued as rs765856240; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GLIS3 | c.504G>A p.S168= | Silent (SNP) | VAF 52/908 reads (6%) | catalogued as rs201431173; called by muse, mutect2
- IFI16 | c.2241C>T p.T747= (on ENST00000295809 / NM_001364867.2; = p.T691= on NM_005531.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 31/91 reads (34%) | catalogued as rs753132913; called by muse, mutect2, varscan2
- INPP5K | c.1158G>A p.K386= | Silent (SNP) | VAF 84/434 reads (19%) | called by muse, mutect2, varscan2
- ITIH6 | c.390C>T p.F130= | Silent (SNP) | VAF 75/589 reads (13%) | catalogued as rs768802632, COSV99513867; called by muse, mutect2, varscan2
- KCNA1 | c.231G>A p.R77= | Silent (SNP) | VAF 37/972 reads (4%) | catalogued as COSV66836398, COSV66838585; called by muse, mutect2
- MEI1 | c.18G>A p.A6= | Silent (SNP) | VAF 15/88 reads (17%) | called by muse, mutect2, varscan2
- MYO15A | c.1743G>A p.S581= | Silent (SNP) | VAF 8/128 reads (6%) | catalogued as rs1454939553, COSV99234446; called by muse, mutect2
- NINL | c.2454C>T p.D818= | Silent (SNP) | VAF 68/273 reads (25%) | catalogued as rs142117050; called by muse, mutect2, varscan2
- NOM1 | c.2322C>T p.D774= | Silent (SNP) | VAF 12/133 reads (9%) | called by muse, mutect2
- OGT | c.2019C>T p.F673= | Silent (SNP) | VAF 24/109 reads (22%) | catalogued as COSV65482048; called by muse, mutect2, varscan2
- OR2W1 | c.684G>A p.T228= | Silent (SNP) | VAF 107/491 reads (22%) | catalogued as rs144276666, COSV65851448; called by muse, mutect2, varscan2
- PCDHB2 | c.2019G>T p.L673= | Silent (SNP) | VAF 50/788 reads (6%) | called by muse, mutect2
- PTPRU | c.4149G>C p.G1383= | Silent (SNP) | VAF 15/132 reads (11%) | called by muse, mutect2, varscan2
- REG3A | c.339C>T p.T113= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs143057391; called by muse, mutect2, varscan2
- ROBO3 | c.402G>A p.A134= | Silent (SNP) | VAF 12/65 reads (18%) | called by muse, mutect2, varscan2
- S1PR5 | c.204C>T p.H68= | Silent (SNP) | VAF 61/341 reads (18%) | called by muse, mutect2, varscan2
- SLC22A18 | c.324C>T p.A108= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs912525177; called by muse, mutect2, varscan2
- THBS2 | c.288C>T p.S96= | Silent (SNP) | VAF 37/548 reads (7%) | called by muse, mutect2
- TMEM151B | c.810C>T p.R270= | Silent (SNP) | VAF 32/452 reads (7%) | called by muse, mutect2
- USP20 | c.1296C>T p.G432= | Silent (SNP) | VAF 87/408 reads (21%) | called by muse, mutect2, varscan2
- VWDE | c.4467C>T p.I1489= | Silent (SNP) | VAF 57/293 reads (19%) | called by muse, mutect2, varscan2
- ZIC4 | c.342C>T p.G114= | Silent (SNP) | VAF 142/610 reads (23%) | catalogued as COSV101267960; called by mutect2, varscan2
- ABLIM3 | c.335+649C>T | Intron (SNP) | VAF 50/176 reads (28%) | called by muse, mutect2
- AC244517.10 | c.36-10462C>T | Intron (SNP) | VAF 58/317 reads (18%) | catalogued as rs969416383; called by muse, mutect2, varscan2
- ANTXR1 | c.1185+51G>A | Intron (SNP) | VAF 94/420 reads (22%) | catalogued as rs1418776341; called by muse, mutect2, varscan2
- ATP10A | c.3166-120C>T | Intron (SNP) | VAF 17/206 reads (8%) | catalogued as rs761352615; called by muse, mutect2
- BRD1 | c.2360-56C>T | Intron (SNP) | VAF 145/541 reads (27%) | called by muse, mutect2, varscan2
- C8orf31 | n.700A>C | RNA (SNP) | VAF 12/144 reads (8%) | called by muse, mutect2
- DMAC2 | chr19:41440092 G>C | 5'Flank (SNP) | VAF 38/204 reads (19%) | called by muse, mutect2, varscan2
- EDC4 | c.3443-18C>T | Intron (SNP) | VAF 99/487 reads (20%) | catalogued as rs759870716, COSV59303484; called by muse, mutect2, varscan2
- GDAP1L1 | c.374-11G>A | Intron (SNP) | VAF 92/221 reads (42%) | catalogued as COSV61157871; called by muse, mutect2, varscan2
- GRID2IP | c.584+2864A>G | Intron (SNP) | VAF 29/161 reads (18%) | catalogued as rs1444737565; called by muse, mutect2, varscan2
- INTS4 | c.2228+12G>A | Intron (SNP) | VAF 25/102 reads (25%) | called by muse, mutect2, varscan2
- KCNH2 | c.1128+1802C>T | Intron (SNP) | VAF 42/189 reads (22%) | catalogued as rs199794297; called by muse, mutect2, varscan2
- LINC02054 | n.80C>T | RNA (SNP) | VAF 31/136 reads (23%) | called by muse, mutect2, varscan2
- MAN2C1 | c.791-519G>A | Intron (SNP) | VAF 21/152 reads (14%) | called by muse, mutect2, varscan2
- MTMR1 | c.1057-1087G>C | Intron (SNP) | VAF 8/114 reads (7%) | called by muse, mutect2
- NRG1 | c.502+31419G>A | Intron (SNP) | VAF 146/398 reads (37%) | catalogued as rs550578958, COSV55162087; called by muse, varscan2
- OVCH1-AS1 | n.503G>A | RNA (SNP) | VAF 58/307 reads (19%) | called by muse, mutect2, varscan2
- PAK1 | c.*88C>T | 3'UTR (SNP) | VAF 51/233 reads (22%) | called by muse, mutect2, varscan2
- PHIP | c.41-40G>A | Intron (SNP) | VAF 48/139 reads (35%) | catalogued as rs766255953; called by muse, mutect2, varscan2
- POLR3G | c.247+2532G>A | Intron (SNP) | VAF 13/59 reads (22%) | catalogued as rs1464547436; called by muse, mutect2, varscan2
- RPS17 | c.261+38C>T | Intron (SNP) | VAF 20/340 reads (6%) | called by muse, mutect2
- SRL | c.62-3371C>T | Intron (SNP) | VAF 18/129 reads (14%) | catalogued as rs572053170; called by muse, mutect2, varscan2
- STMN4 | c.510+34G>A | Intron (SNP) | VAF 52/231 reads (23%) | called by muse, mutect2, varscan2
- SVIL2P | n.2092T>C | RNA (SNP) | VAF 36/170 reads (21%) | called by muse, mutect2, varscan2
- TCF7L2 | c.1442+685G>C | Intron (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
